Somatic mutation profile of tumor specimen MMRF_1822_1_BM_CD138pos (aliquot MMRF_1822_1_BM_CD138pos_T1_KBS5U_K11315) from MMRF case MMRF_1822, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 43.1 years (15,759 days).
Specimen MMRF_1822_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0273a782-0e30-460c-8b46-65f18a5a6ed5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1822_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1822_1_PB_Whole_C2_KBS5U_K11316; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79601a6d-73f1-463c-9b2a-db911aad1114

The open-access MAF lists 94 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 19, Intron 15, Silent 10, 5'UTR 6, Splice Site 3, Nonsense Mutation 3, 3'Flank 2, 5'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD4 | c.5293G>A p.E1765K (on ENST00000357008 / NM_001363606.2; = p.E1776K on NM_001273.5) | Missense Mutation (SNP) | VAF 91/167 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58897080; called by muse, mutect2, varscan2
- CPTP | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.114); catalogued as rs772806832, COSV100028029; called by muse, mutect2, varscan2
- DIS3 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340484781; called by muse, mutect2, varscan2
- DNAJC6 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 89/163 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs767476436, COSV54778733; called by muse, mutect2, varscan2
- ECSIT | c.796+8C>T | Splice Region (SNP) | VAF 10/152 reads (7%) | catalogued as rs777510262; called by muse, mutect2
- IGHV2-70 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs370008108; called by muse, varscan2
- IGKV4-1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.129); catalogued as rs142986022; called by muse, mutect2, varscan2
- IGLV3-1 | c.160T>G p.Y54D | Missense Mutation (SNP) | VAF 61/65 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs61731690; called by muse, mutect2, varscan2
- IGLV5-45 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs778490423; called by muse, varscan2
- KRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55534434, COSV55579983, COSV55703886; called by muse, mutect2, varscan2
- MC2R | c.233T>A p.I78N | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs1349615874; called by muse, mutect2, varscan2
- MTMR7 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 89/179 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866932036, COSV99471924; called by muse, mutect2, varscan2
- OR4S1 | c.741G>T p.L247F | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as rs751056004; called by muse, mutect2, varscan2
- PIK3C2G | c.3710C>T p.S1237F (on ENST00000676171; = p.S1196F on NM_004570.5) | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.591); catalogued as rs950782237, COSV56840543; called by muse, mutect2
- RBMS3 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 126/275 reads (46%) | catalogued as COSV56150262; called by muse, mutect2, varscan2
- RPL5 | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV100240398; called by muse, mutect2, varscan2
- SNRNP70 | c.1017_1025del p.D341_P343del | In Frame Del (DEL) | VAF 31/64 reads (48%) | catalogued as rs1260834199; called by mutect2, varscan2
- USP25 | c.540T>G p.F180L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53481412; called by muse, mutect2, varscan2
- DNAJC14 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 90/197 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FSIP2 | c.11698A>C p.S3900R | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSYN2A | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCTD19 | c.782G>C p.C261S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.9488C>A p.T3163N | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MAP3K1 | c.4190C>G p.S1397* | Nonsense Mutation (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- MMP19 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NCSTN | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- PCDHGA1 | c.249C>G p.S83R | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PCGF6 | c.810+2T>G p.X270_splice (on ENST00000369847 / NM_001011663.2; = p.X195_splice on NM_032154.4) | Splice Site (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- PFKP | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3CD | c.2719-2A>G p.X907_splice | Splice Site (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- PRKD2 | c.1151T>A p.V384E | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SAMD9L | c.1700T>G p.F567C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SMARCC2 | c.2002C>A p.Q668K | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TRAF2 | c.267+1G>A p.X89_splice | Splice Site (SNP) | VAF 115/124 reads (93%) | called by muse, mutect2, varscan2
- UST | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.179); called by muse, mutect2
- VPS13B | c.3661C>A p.P1221T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2
- ZCCHC2 | c.3160A>G p.I1054V | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZEB2 | c.3335A>T p.Y1112F | Missense Mutation (SNP) | VAF 177/380 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ZFP36L1 | c.388A>G p.K130E | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF598 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZSWIM5 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- AKR1C1 | c.642T>G p.V214= | Silent (SNP) | VAF 89/182 reads (49%) | called by muse, mutect2, varscan2
- CFAP126 | c.474C>T p.L158= | Silent (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- FANCM | c.5352T>G p.A1784= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- GOT1L1 | c.1125C>T p.N375= | Silent (SNP) | VAF 84/182 reads (46%) | catalogued as rs372052967, COSV100294751, COSV56877058; called by muse, mutect2, varscan2
- HOXB3 | c.999C>A p.V333= | Silent (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.291G>A p.G97= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs529103938; called by muse, varscan2
- IGLV5-45 | c.153C>G p.T51= | Silent (SNP) | VAF 72/176 reads (41%) | catalogued as rs187280500; called by muse, varscan2
- SHANK1 | c.3873C>T p.G1291= | Silent (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- TNKS | c.180G>A p.R60= | Silent (SNP) | VAF 3/53 reads (6%) | catalogued as rs974784627; called by muse, mutect2
- VPS26B | c.456C>T p.L152= | Silent (SNP) | VAF 66/148 reads (45%) | called by muse, mutect2, varscan2
- ABLIM1 | c.-70G>C | 5'UTR (SNP) | VAF 15/227 reads (7%) | called by muse, mutect2
- ADD2 | c.*1237G>A | 3'UTR (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- ADH6 | c.120+71A>C | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- ANO5 | c.*3307A>T | 3'UTR (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- APBA2 | c.1524+43A>T | Intron (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- APOM | c.541+153A>T | Intron (SNP) | VAF 132/281 reads (47%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.829-20A>G | Intron (SNP) | VAF 55/112 reads (49%) | called by muse, mutect2, varscan2
- CEP41 | c.*500C>T | 3'UTR (SNP) | VAF 30/55 reads (55%) | catalogued as rs559935453; called by muse, mutect2, varscan2
- EDARADD | c.*1950C>T | 3'UTR (SNP) | VAF 37/80 reads (46%) | catalogued as rs547079176, COSV100512670; called by muse, mutect2
- FAM107B | chr10:14519134 G>C | 3'Flank (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- FAM13A | c.759+435C>T | Intron (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- FAP | c.-44G>A | 5'UTR (SNP) | VAF 24/436 reads (6%) | catalogued as rs774278037, COSV51864408; called by muse, mutect2
- FMR1 | c.*191G>A | 3'UTR (SNP) | VAF 62/69 reads (90%) | called by muse, mutect2, varscan2
- FNDC1 | c.*323A>G | 3'UTR (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- FRY | c.*726G>T | 3'UTR (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
- HLA-DMB | c.-188A>C | 5'UTR (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- JAM2 | c.*1125C>T | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- LRATD1 | c.*5111T>C | 3'UTR (SNP) | VAF 5/75 reads (7%) | catalogued as rs1360730277; called by muse, mutect2
- LRRIQ3 | c.*403T>C | 3'UTR (SNP) | VAF 35/213 reads (16%) | called by muse, mutect2, varscan2
- NCAPG2 | c.3380+3026G>A | Intron (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2
- NECAB2 | c.597-758T>C | Intron (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- OLFM3 | c.653-6878G>T | Intron (SNP) | VAF 69/141 reads (49%) | called by muse, mutect2, varscan2
- OXNAD1 | c.*1557G>A | 3'UTR (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2, varscan2
- OXTR | c.-3G>T | 5'UTR (SNP) | VAF 16/29 reads (55%) | catalogued as rs1430454165; called by muse, mutect2, varscan2
- POLR3G | c.*40A>G | 3'UTR (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- RAB40C | chr16:630422 C>T | 3'Flank (SNP) | VAF 36/59 reads (61%) | called by muse, mutect2, varscan2
- RAB5B | c.*2330_*2332del | 3'UTR (DEL) | VAF 56/122 reads (46%) | called by mutect2, pindel, varscan2
- RAPGEF5 | c.*443T>A | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- RBFOX1 | c.1072-158C>T | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- RPL4 | c.175+11A>T | Intron (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- RSBN1 | c.*1099T>A | 3'UTR (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+743C>G | Intron (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- SCN1A | c.4852+41del | Intron (DEL) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- SEMA5A | c.*3360T>A | 3'UTR (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- SEMA6A | c.1730-1003C>G | Intron (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- SHISAL2B | c.*30G>A | 3'UTR (SNP) | VAF 21/364 reads (6%) | called by muse, mutect2
- SKA2 | c.*46C>G | 3'UTR (SNP) | VAF 112/228 reads (49%) | called by muse, varscan2
- SPEF2 | c.-126A>G | 5'UTR (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- STIMATE | c.*1672_*1686delinsTTGGGTCCGAATTGT | 3'UTR (ONP) | VAF 56/169 reads (33%) | called by mutect2*, pindel, varscan2*
- TEX22 | c.-7G>A | 5'UTR (SNP) | VAF 65/115 reads (57%) | catalogued as rs1382642206; called by muse, mutect2, varscan2
- TRIM74 | chr7:72969826 G>A | 5'Flank (SNP) | VAF 8/23 reads (35%) | catalogued as rs1554508133; called by muse, mutect2, varscan2
- WDR11 | c.3291+44T>C | Intron (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- XBP1 | c.227+168G>A | Intron (SNP) | VAF 36/73 reads (49%) | catalogued as rs1569205501; called by muse, mutect2, varscan2
